Somatic mutation profile of tumor specimen HCM-CSHL-0509-C24-06A (aliquot HCM-CSHL-0509-C24-06A-11D-A82H-36) from HCMI case HCM-CSHL-0509-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.8 years (26,219 days).
Specimen HCM-CSHL-0509-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c50ba651-9a2d-44da-bdd1-d9513e585df0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0509-C24-11A (Solid Tissue Normal), aliquot HCM-CSHL-0509-C24-11A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7446e79-1b8d-450c-bd0f-37c9eff171ca

The open-access MAF lists 84 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 21, Splice Region 4, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Ins 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 149/374 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KBTBD13 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 162/773 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1303411209; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ACSL6 | c.99G>A p.M33I (on ENST00000379240; = p.M58I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/409 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99734317; called by muse, mutect2, varscan2
- ATP1A3 | c.3022C>T p.R1008C (on ENST00000545399 / NM_001256214.2; = p.R995C on NM_152296.5) | Missense Mutation (SNP) | VAF 160/356 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57485526, COSV57486287; called by muse, varscan2
- ATP2B1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 141/368 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV99665460; called by muse, mutect2, varscan2
- CAD | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53033488; called by muse, mutect2, varscan2
- CDKL5 | c.555C>T p.G185= | Splice Region (SNP) | VAF 101/121 reads (83%) | catalogued as rs904580767, COSV66112914; called by muse, mutect2, varscan2
- CENPP | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 152/470 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781488340; called by muse, varscan2
- DNAH6 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs770563696, COSV52870849; called by muse, mutect2, varscan2
- DSG4 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV57389889; called by muse, mutect2, varscan2
- FAM170B | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 240/580 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs373146727, COSV61254163; called by muse, varscan2
- FAM184A | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs780653028, COSV58852197; called by muse, mutect2, varscan2
- FZD5 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 31/885 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs1223250135; called by muse, mutect2
- GRIA1 | c.1160A>C p.K387T | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.134); catalogued as COSV53589598; called by muse, varscan2
- HEY2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 219/544 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs113023735, COSV100856409, COSV64240744; called by muse, mutect2, varscan2
- KCNB1 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65571493; called by muse, varscan2
- LAMA1 | c.2700C>T p.R900= | Splice Region (SNP) | VAF 77/220 reads (35%) | catalogued as rs140067215; called by muse, mutect2, varscan2
- PAOX | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 141/396 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs749327396, COSV53372087, COSV99530172; called by muse, mutect2, varscan2
- PCDHA10 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100249716, COSV56532810; called by muse, mutect2, varscan2
- POU2F2 | c.922G>A p.V308I (on ENST00000526816 / NM_001207025.3; = p.V292I on NM_002698.5) | Missense Mutation (SNP) | VAF 149/412 reads (36%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.912); catalogued as rs988567070; called by muse, mutect2, varscan2
- RAB31 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482555508, COSV71261792; called by muse, mutect2, varscan2
- RAB37 | c.183G>A p.T61= | Splice Region (SNP) | VAF 136/294 reads (46%) | catalogued as rs759047469, COSV61192454; called by muse, mutect2, varscan2
- RYR2 | c.1614G>A p.A538= | Splice Region (SNP) | VAF 66/173 reads (38%) | catalogued as rs566885717, COSV63688605; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SACS | c.4502G>A p.R1501K | Missense Mutation (SNP) | VAF 112/290 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101207499; called by muse, mutect2, varscan2
- SCEL | c.896G>A p.R299Q (on ENST00000349847 / NM_144777.3; = p.R279Q on NM_003843.4) | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.029); catalogued as rs149394221; called by muse, mutect2, varscan2
- SFMBT2 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 46/158 reads (29%) | catalogued as COSV62811139; called by muse, mutect2, varscan2
- TNNT2 | c.886C>T p.R296C (on ENST00000236918; = p.R293C on NM_000364.4) | Missense Mutation (SNP) | VAF 187/472 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs367785431, CM031385, COSV52664595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WIPI2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 165/436 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.394); catalogued as rs765007819, COSV56591964; called by muse, mutect2, varscan2
- ZFHX4 | c.9001G>A p.G3001R | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs772582651, COSV50490189; called by muse, varscan2
- ZNF654 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368258034; called by muse, mutect2, varscan2
- ATF6B | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CEP78 | c.137A>T p.N46I | Missense Mutation (SNP) | VAF 365/893 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2
- CNTN1 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 89/112 reads (79%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CRISPLD1 | c.1385A>C p.D462A | Missense Mutation (SNP) | VAF 110/300 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DDX11 | c.2572_2574dup p.A858dup (on ENST00000545668 / NM_152438.2; = p.L811dup on NM_004399.3) | In Frame Ins (INS) | VAF 170/453 reads (38%) | called by mutect2, pindel, varscan2
- FAAH2 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 85/97 reads (88%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FAM171A2 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GABRG3 | c.1073del p.P358Qfs*11 | Frame Shift Del (DEL) | VAF 90/227 reads (40%) | called by mutect2, pindel, varscan2
- HIPK1 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INSYN2B | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 167/400 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- IRF1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KCNJ3 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- KIF15 | c.1481G>A p.R494K | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LRP1B | c.12811C>A p.P4271T | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MRAP2 | c.609C>A p.D203E | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2
- MSH4 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PKDREJ | c.970T>A p.S324T | Missense Mutation (SNP) | VAF 175/370 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PLCZ1 | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPM1N | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 259/651 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIC1 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 126/297 reads (42%) | called by muse, mutect2, varscan2
- RYR3 | c.13978T>C p.S4660P (on ENST00000389232; = p.S4661P on NM_001036.6) | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLC39A11 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 129/328 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC44A1 | c.1273T>C p.F425L | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SPDL1 | c.517dup p.M173Nfs*14 | Frame Shift Ins (INS) | VAF 74/160 reads (46%) | called by mutect2, varscan2
- SSH2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 105/294 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TAX1BP1 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBC1D31 | c.1330C>A p.H444N | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- USP17L1 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB10 | c.1302A>T p.Q434H | Missense Mutation (SNP) | VAF 123/312 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACACB | c.6288G>T p.V2096= | Silent (SNP) | VAF 134/358 reads (37%) | catalogued as COSV58148884, COSV58149646; called by muse, mutect2, varscan2
- ARHGAP25 | c.93G>A p.Q31= (on ENST00000409202 / NM_001007231.3; = p.Q24= on NM_014882.3) | Silent (SNP) | VAF 138/392 reads (35%) | catalogued as rs868045570, COSV54902218; called by muse, mutect2, varscan2
- BASP1 | c.333C>T p.P111= | Silent (SNP) | VAF 257/598 reads (43%) | catalogued as rs1237401196; called by muse, mutect2, varscan2
- C4BPA | c.252C>G p.G84= | Silent (SNP) | VAF 104/261 reads (40%) | called by muse, mutect2, varscan2
- CABP1 | c.786C>T p.T262= (on ENST00000316803 / NM_001033677.1; = p.T59= on NM_004276.5) | Silent (SNP) | VAF 185/440 reads (42%) | catalogued as rs564070934, COSV99974721; called by muse, mutect2, varscan2
- CHMP3 | c.312G>T p.L104= | Silent (SNP) | VAF 63/287 reads (22%) | catalogued as rs755651200; called by muse, mutect2, varscan2
- COL6A5 | c.967A>C p.R323= | Silent (SNP) | VAF 136/311 reads (44%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.1086C>T p.I362= | Silent (SNP) | VAF 205/253 reads (81%) | called by muse, mutect2, varscan2
- DCP2 | c.819C>T p.F273= | Silent (SNP) | VAF 97/247 reads (39%) | called by muse, mutect2, varscan2
- GNA14 | c.384C>T p.I128= | Silent (SNP) | VAF 169/444 reads (38%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.624C>T p.D208= | Silent (SNP) | VAF 110/296 reads (37%) | catalogued as rs369654526; called by muse, varscan2
- IGHV3-53 | c.141C>T p.T47= | Silent (SNP) | VAF 48/178 reads (27%) | catalogued as rs781992517; called by muse, mutect2, varscan2
- IGHV3-66 | c.141C>T p.T47= | Silent (SNP) | VAF 71/484 reads (15%) | catalogued as rs782347421; called by muse, mutect2, varscan2
- KCNT1 | c.915C>A p.I305= (on ENST00000488444; = p.I324= on NM_020822.3) | Silent (SNP) | VAF 192/511 reads (38%) | called by muse, mutect2, varscan2
- PROB1 | c.42G>A p.P14= | Silent (SNP) | VAF 201/510 reads (39%) | called by muse, varscan2
- SEMA4F | c.883C>T p.L295= | Silent (SNP) | VAF 183/480 reads (38%) | catalogued as rs916922086; called by muse, mutect2, varscan2
- SLC7A14 | c.21G>A p.S7= | Silent (SNP) | VAF 120/290 reads (41%) | catalogued as COSV51577913; called by muse, mutect2, varscan2
- SOD1 | c.225A>G p.P75= | Silent (SNP) | VAF 93/229 reads (41%) | called by muse, mutect2, varscan2
- SORBS2 | c.2727G>A p.V909= (on ENST00000284776 / NM_021069.5; = p.V475= on NM_003603.6) | Silent (SNP) | VAF 94/229 reads (41%) | called by muse, mutect2, varscan2
- WSCD2 | c.513C>T p.G171= | Silent (SNP) | VAF 126/333 reads (38%) | catalogued as rs766850790, COSV54579301; called by muse, mutect2, varscan2
- XKR4 | c.267C>T p.G89= | Silent (SNP) | VAF 96/212 reads (45%) | called by mutect2, varscan2
- EFCAB5 | c.2738-4562G>A | Intron (SNP) | VAF 12/55 reads (22%) | called by muse, varscan2
- OBSCN | c.6755-97C>T | Intron (SNP) | VAF 132/343 reads (38%) | catalogued as rs747944570; called by muse, mutect2, varscan2
- TMEM99 | n.800G>A | RNA (SNP) | VAF 153/349 reads (44%) | catalogued as rs528693743; called by muse, mutect2, varscan2
- ZNF83 | c.-166C>G | 5'UTR (SNP) | VAF 81/187 reads (43%) | called by muse, mutect2, varscan2
